Surgical pathology report (de-identified scan), TCGA case TCGA-RP-A693, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RP-A693-06A (Metastatic).

Tumor ID

ICD-O-3
Melanoma, malignant NOS
8720/3
Site Y Brain NOS C71.9
JW 6/28/13

Microscopic Description:

Sections demonstrate sheets and lobules of poorly differentiated epithelioid to spindled malignant cells. These cells contain markedly atypical pleomorphic nuclei and abundant eosinophilic cytoplasm. Patchy brown pigment deposition is epitheliomatous pattern. Scattered mitotic figures as well as foci of necrosis and hemorrhage are noted. The tumor shows an expansive interface with the surrounding brain parenchyma, which appears reactive. There is marked cautery artifact, precluding optimal evaluation.

Diagnosis:

Brain tumor

-Metastatic poorly differentiated malignant neoplasm, consistent with known history of metastatic melanoma.

Histology Discrepancy		

Source: NCI Genomic Data Commons file 81370815-a905-480c-8d36-370da7b65fee (TCGA-RP-A693.1BC61B6F-622F-4D98-BBDB-7E48B0271318.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).